Somatic mutation profile of tumor specimen TARGET-10-PASLAB-09A (aliquot TARGET-10-PASLAB-09A-01D) from TARGET case TARGET-10-PASLAB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,757 days).
Specimen TARGET-10-PASLAB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a01ea5a5-76f6-4d01-ab09-bb31d7eb5dfb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASLAB-10A (Blood Derived Normal), aliquot TARGET-10-PASLAB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b847aead-a759-47dd-98ae-699d0a770c5d

The open-access MAF lists 18 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 4, Nonsense Mutation 2, Silent 2, Frame Shift Del 1, In Frame Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C19orf44 | c.1702G>A p.A568T | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs762513557, COSV52225970; called by muse, mutect2, varscan2
- GALNT13 | c.320C>A p.T107K | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV67229272; called by muse, mutect2, varscan2
- GPR50 | c.412C>G p.R138G | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV54440920, COSV99505940; called by muse, mutect2, varscan2
- MYADML2 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs962480461, COSV57999441; called by muse, mutect2, varscan2
- NOTCH1 | c.7541_7542del p.P2514Rfs*4 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | catalogued as rs763016003, COSV53024776; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- NOTCH1 | c.4740_4741insGGG p.M1580_P1581insG | In Frame Ins (INS) | VAF 12/25 reads (48%) | catalogued as CI159419; called by mutect2, pindel, varscan2
- OR1A1 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as rs567237017, COSV58404280; called by muse, mutect2, varscan2
- PLA2G2D | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 9/15 reads (60%) | catalogued as rs768812104, COSV64281794; called by muse, mutect2, varscan2
- PPM1E | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.108); catalogued as COSV57576885; called by muse, mutect2, varscan2
- PTEN | c.700_701delinsTCGTA p.R234delinsS* | Nonsense Mutation (INS) | VAF 25/38 reads (66%) | catalogued as COSV64293797, COSV64299636; called by pindel, varscan2*
- SYNPO | c.1661G>A p.R554H (on ENST00000394243 / NM_001166208.2; = p.R310H on NM_007286.6) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.933); catalogued as rs1348983277, COSV56941454; called by muse, mutect2, varscan2
- DNAH5 | c.9912G>A p.S3304= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs188218914, COSV99445569; called by muse, mutect2, varscan2
- SPAST | c.831A>G p.G277= | Silent (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- ENAH | c.803-43A>G | Intron (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- GREB1 | c.901+89G>T | Intron (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- HDAC4 | c.866-1097C>T | Intron (SNP) | VAF 9/18 reads (50%) | catalogued as rs1161594183; called by muse, mutect2, varscan2
- PIPSL | n.2050G>C | RNA (SNP) | VAF 27/79 reads (34%) | called by muse, mutect2, varscan2
- SLC37A1 | c.138+20C>T | Intron (SNP) | VAF 5/16 reads (31%) | catalogued as rs752611788; called by muse, mutect2
